Somatic mutation profile of tumor specimen MMRF_2015_2_BM_CD138pos (aliquot MMRF_2015_2_BM_CD138pos_T1_KHS5U_L13765) from MMRF case MMRF_2015, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,749 days).
Specimen MMRF_2015_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26b4f258-8b12-45b0-8e5c-25f30c379a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2015_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2015_1_PB_CD3pos_C2_KHS5U_L08091; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c6e2161-efbc-46f6-abfe-7e2060a7ed33

The open-access MAF lists 203 somatic variants for this specimen: 68 protein-altering or splice-affecting, 30 silent, 105 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 53, Silent 30, Intron 27, 5'UTR 9, 5'Flank 8, RNA 7, Nonsense Mutation 5, Splice Site 3, Splice Region 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 60/61 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as COSV57057225; called by muse, mutect2, varscan2
- AC092747.2 | n.860G>A | Splice Region (SNP) | VAF 10/68 reads (15%) | catalogued as rs1275445219; called by muse, mutect2, varscan2
- CATSPER2 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28660230, COSV100390504; called by muse, varscan2
- CEP55 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101016751; called by muse, mutect2, varscan2
- CYLD | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868852255, COSV104410762, COSV61094474; called by muse, mutect2, varscan2
- DCAF10 | c.433T>G p.F145V | Missense Mutation (SNP) | VAF 142/317 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54288494; called by muse, mutect2, varscan2
- DDA1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs766625782, COSV100724772; called by muse, varscan2
- DIPK1C | c.937del p.Q313Kfs*30 | Frame Shift Del (DEL) | VAF 184/458 reads (40%) | catalogued as COSV59725317; called by mutect2, pindel, varscan2
- EPHA5 | c.1985C>A p.A662D | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56668549; called by muse, mutect2, varscan2
- GK5 | c.1049-1G>A p.X350_splice | Splice Site (SNP) | VAF 7/91 reads (8%) | catalogued as COSV101242345; called by muse, mutect2
- GPR22 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 53/101 reads (52%) | catalogued as COSV51767142; called by muse, mutect2, varscan2
- IGHV1-69 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 111/273 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.047); catalogued as rs11557983; called by muse, mutect2, varscan2
- IGHV4-34 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs1354511622; called by muse, mutect2, varscan2
- KLHDC7A | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757275158; called by muse, mutect2, varscan2
- KLHL40 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs762744469; called by muse, mutect2, varscan2
- MAP2 | c.3989A>G p.E1330G | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs976365071; called by muse, mutect2, varscan2
- RSPH14 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320363; called by muse, mutect2
- RTN4RL2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 160/293 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV58652075; called by muse, mutect2, varscan2
- SLC25A17 | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.34); catalogued as COSV99610479; called by muse, mutect2
- SUPT20H | c.1237G>A p.V413I (on ENST00000350612 / NM_001014286.3; = p.V414I on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1183065791; called by muse, mutect2, varscan2
- TOX2 | c.984G>T p.M328I (on ENST00000358131 / NM_001098798.2; = p.M304I on NM_032883.3) | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV57881970; called by muse, mutect2, varscan2
- UNC13C | c.6068C>T p.A2023V | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.185); catalogued as rs371933638; called by muse, mutect2
- ZBTB38 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 167/333 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747459711, COSV58540119; called by muse, mutect2, varscan2
- ACSS2 | c.1903+2T>G p.X635_splice | Splice Site (SNP) | VAF 6/178 reads (3%) | called by muse, mutect2
- ADAMTS13 | c.2755T>C p.C919R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL5 | c.253-2A>T p.X85_splice | Splice Site (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2
- AHDC1 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 86/170 reads (51%) | called by muse, mutect2, varscan2
- AMBRA1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ANAPC2 | c.960_973del p.R322Pfs*69 | Frame Shift Del (DEL) | VAF 83/174 reads (48%) | called by mutect2, pindel, varscan2
- ANKRD2 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2
- ARMCX5-GPRASP2 | c.1469T>G p.L490* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- BASP1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BSPRY | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD6 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CCDC160 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- CCKAR | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPAMD8 | c.4145T>C p.L1382P (on ENST00000651564; = p.L1335P on NM_015692.5) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRELD1 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CRLF2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); called by muse, varscan2
- DHX15 | c.1787-5T>G | Splice Region (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- FARP1 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GDI1 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GOLPH3 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- IGKJ4 | c.2T>G p.L1R | Missense Mutation (SNP) | VAF 55/118 reads (47%) | PolyPhen benign (0.062); called by muse, varscan2
- LRFN2 | c.1081G>C p.A361P | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYST | c.1933G>T p.D645Y | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MARS1 | c.539A>C p.E180A | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MLIP | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 146/259 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MXRA5 | c.4760C>A p.P1587Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); called by muse, mutect2
- NPTXR | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NTF4 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT tolerated (0.16); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PARD3B | c.3034C>A p.P1012T (on ENST00000406610 / NM_001302769.2; = p.P943T on NM_057177.7) | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- POF1B | c.1670T>C p.I557T | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- POM121L2 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2
- PRKD2 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTCHD1 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- RHCE | c.1114T>G p.L372V | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); called by muse, mutect2
- SHD | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 26/395 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- SLC14A1 | c.1047C>G p.F349L | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SNRPB | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA2L | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUN2 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 25/377 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2
- TSNAX | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR4 | c.10347T>A p.D3449E | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VMA21 | c.29A>T p.N10I | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, varscan2
- XIAP | c.1116A>C p.Q372H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- ZNF454 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCG5 | c.1311C>T p.N437= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs575266356, CM012721, COSV53213025; ClinVar: uncertain significance; called by mutect2, varscan2
- ACTN2 | c.771G>A p.A257= | Silent (SNP) | VAF 100/193 reads (52%) | catalogued as rs201545916, COSV100856632, COSV63978506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRF2 | c.693G>A p.E231= (on ENST00000296862 / NM_001368115.2; = p.E163= on NM_153839.7) | Silent (SNP) | VAF 12/412 reads (3%) | called by muse, mutect2
- AK5 | c.1317C>T p.I439= (on ENST00000354567 / NM_174858.3; = p.I413= on NM_012093.4) | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as rs538601394, COSV60974482; called by muse, mutect2, varscan2
- ATOH1 | c.834C>G p.A278= | Silent (SNP) | VAF 12/133 reads (9%) | called by muse, mutect2
- CHST5 | c.1002C>T p.I334= | Silent (SNP) | VAF 8/163 reads (5%) | catalogued as COSV60339242; called by muse, mutect2
- CNTNAP5 | c.1927C>A p.R643= | Silent (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- CRYBG2 | c.2037T>C p.D679= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs892160702; called by muse, mutect2
- DCAF5 | c.48C>T p.G16= | Silent (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- DNER | c.156C>A p.P52= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- FBN3 | c.3330C>T p.A1110= | Silent (SNP) | VAF 31/462 reads (7%) | called by muse, mutect2
- IGHV2-70 | c.123C>T p.C41= | Silent (SNP) | VAF 47/51 reads (92%) | catalogued as rs377265996; called by muse, varscan2
- IGHV2-70 | c.120C>T p.T40= | Silent (SNP) | VAF 47/51 reads (92%) | catalogued as rs538449396; called by muse, varscan2
- LPCAT3 | c.111G>T p.A37= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- MIB1 | c.519A>T p.G173= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- MYCN | c.285C>T p.D95= | Silent (SNP) | VAF 68/169 reads (40%) | called by muse, mutect2, varscan2
- NPAS3 | c.507A>G p.G169= (on ENST00000356141 / NM_001164749.2; = p.G137= on NM_022123.3) | Silent (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- PGK2 | c.93G>A p.K31= | Silent (SNP) | VAF 73/157 reads (46%) | called by muse, mutect2, varscan2
- PSAT1 | c.1071G>A p.L357= (on ENST00000376588 / NM_058179.4; = p.L311= on NM_021154.5) | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- PSME4 | c.2544G>A p.E848= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV66367683; called by muse, mutect2
- PZP | c.2715C>G p.V905= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV54359310, COSV54369307; called by muse, mutect2
- SENP5 | c.969G>T p.V323= | Silent (SNP) | VAF 20/273 reads (7%) | called by muse, mutect2
- SORL1 | c.192G>A p.G64= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, varscan2
- STAB2 | c.1155C>G p.T385= | Silent (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- TAOK2 | c.1275A>G p.L425= | Silent (SNP) | VAF 143/1204 reads (12%) | catalogued as rs147979834; called by muse, mutect2, varscan2
- TBC1D1 | c.1836G>T p.R612= | Silent (SNP) | VAF 12/349 reads (3%) | called by muse, mutect2
- TMPRSS6 | c.1611G>A p.K537= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- TOLLIP | c.756G>A p.V252= | Silent (SNP) | VAF 25/440 reads (6%) | called by muse, mutect2
- XDH | c.3675T>A p.P1225= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- XIRP2 | c.9087G>A p.P3029= (on ENST00000628543; = p.P3204= on NM_152381.6) | Silent (SNP) | VAF 65/144 reads (45%) | catalogued as rs1397308081, COSV54702383; called by muse, mutect2
- ABCG4 | c.239-824G>T | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- ABTB2 | c.*376C>A | 3'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- AC093791.1 | n.340C>A | RNA (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- AFF2 | c.*8268_*8296del | 3'UTR (DEL) | VAF 9/28 reads (32%) | called by muse*, mutect2, varscan2*
- AL592293.1 | n.984A>G | RNA (SNP) | VAF 39/39 reads (100%) | called by muse, mutect2, varscan2
- ANOS1 | c.*1177T>A | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- AP1S3 | c.430-5511G>C | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- AR | c.-412C>A | 5'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- ATP5MC1 | c.-9-56A>G | Intron (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- BACH2 | c.*2465G>T | 3'UTR (SNP) | VAF 39/39 reads (100%) | called by muse, mutect2, varscan2
- BCL2 | c.*4713G>T | 3'UTR (SNP) | VAF 10/77 reads (13%) | catalogued as rs1376026145; called by muse, mutect2, varscan2
- BCL7A | chr12:122020689 T>G | 5'Flank (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2
- C16orf54 | c.*957A>G | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- CACNA1C | c.*587C>T | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- CACNA1C | c.*588G>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- CBARP | c.293-96C>T | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- CCDC6 | c.*2670C>G | 3'UTR (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- CD99 | c.67+599G>A | Intron (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*2137C>T | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CLEC2A | c.*165A>C | 3'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- CNTN3 | c.*228A>G | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- COL5A2 | c.*678_*685del | 3'UTR (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- COPS8 | c.*179C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CREG2 | c.*818A>T | 3'UTR (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- CTTNBP2 | c.2069-1966A>T | Intron (SNP) | VAF 6/85 reads (7%) | catalogued as COSV50499483; called by muse, mutect2
- DDHD2 | c.1126-614A>G | Intron (SNP) | VAF 25/25 reads (100%) | called by muse, mutect2, varscan2
- DENND2B | c.*387C>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- DLGAP1 | c.*2195T>G | 3'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- EIF3G | c.151+16C>A | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- EIF4A2 | c.208+128G>A | Intron (SNP) | VAF 206/534 reads (39%) | catalogued as COSV100125573; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1512+821G>A | Intron (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- ERAP1 | c.*514G>C | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- FBXO30 | c.*560A>G | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- FSTL5 | c.*629G>C | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- GABRG2 | c.1248+155G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- GEM | c.331+36A>G | Intron (SNP) | VAF 14/25 reads (56%) | called by muse, varscan2
- GFER | c.456-42G>A | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- GLRX | c.208-9C>A | Intron (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- GOLM1 | c.*941T>G | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- GOLT1B | c.*2197G>T | 3'UTR (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- GRIK3 | c.*1969T>A | 3'UTR (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- GYPA | c.*472T>C | 3'UTR (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- HDAC4 | c.2265+55G>A | Intron (SNP) | VAF 18/268 reads (7%) | catalogued as rs868340233; called by muse, mutect2
- HMGCS1 | c.448+60C>T | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- HNRNPA1P22 | chr3:42887644 A>C | 5'Flank (SNP) | VAF 14/167 reads (8%) | catalogued as rs1316756894; called by muse, mutect2
- HSD17B11 | c.*641G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.171A>T | RNA (SNP) | VAF 68/198 reads (34%) | catalogued as rs746861388; called by muse, mutect2, varscan2
- IGKV2-29 | n.57G>A | RNA (SNP) | VAF 96/266 reads (36%) | catalogued as rs777860767; called by muse, mutect2
- IGLL5 | c.-146G>A | 5'UTR (SNP) | VAF 60/126 reads (48%) | catalogued as rs1432501105; called by muse, mutect2, varscan2
- IMMP2L | c.305+553A>T | Intron (SNP) | VAF 71/172 reads (41%) | called by muse, mutect2, varscan2
- JPH3 | c.-281C>G | 5'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2
- KCTD17 | c.211-524C>G | Intron (SNP) | VAF 15/430 reads (3%) | called by muse, mutect2
- KLF13 | c.*2214G>A | 3'UTR (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- KLF6 | c.-74A>C | 5'UTR (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- LIFR | c.*5028A>G | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- LIMD2 | c.43-14C>T | Intron (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- LMLN | c.*4896T>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | catalogued as rs929426679; called by muse, mutect2, varscan2
- LRRN4 | c.*266T>G | 3'UTR (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- MIR5195 | chr14:106851316 T>A | 5'Flank (SNP) | VAF 98/198 reads (49%) | called by muse, varscan2
- MIR5195 | chr14:106851370 T>C | 5'Flank (SNP) | VAF 74/169 reads (44%) | catalogued as rs1263321431; called by muse, varscan2
- MLC1 | c.*120C>G | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- MOB1B | c.409+41C>G | Intron (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- MUCL1 | c.-14G>T | 5'UTR (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- NCAPD3 | c.*1119C>A | 3'UTR (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- NTRK3 | c.*5522C>G | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- NUBP1 | chr16:10743810 C>A | 5'Flank (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- PARVA | c.*586T>G | 3'UTR (SNP) | VAF 58/111 reads (52%) | called by muse, mutect2, varscan2
- PCOLCE2 | chr3:142889098 G>A | 5'Flank (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PDPK2P | n.357C>T | RNA (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- PHC1P1 | n.723C>T | RNA (SNP) | VAF 13/228 reads (6%) | catalogued as rs965773438; called by muse, mutect2
- PLXNA4 | c.*4427T>G | 3'UTR (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- PLXNA4 | c.1372-86483C>T | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- PTGER3 | c.*588G>A | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, varscan2
- PTGER3 | c.1077+388G>A | Intron (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- PTPN3 | c.*1354C>T | 3'UTR (SNP) | VAF 11/132 reads (8%) | catalogued as rs1456886847; called by muse, mutect2
- RHD | c.*217C>A | 3'UTR (SNP) | VAF 26/186 reads (14%) | called by muse, mutect2, varscan2
- RNA5S17 | chr1:228650707 G>T | 5'Flank (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- RNF216 | c.*454G>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- RXFP3 | c.-332A>G | 5'UTR (SNP) | VAF 60/120 reads (50%) | catalogued as rs1342561727; called by muse, mutect2, varscan2
- SBK1 | c.*1919C>T | 3'UTR (SNP) | VAF 62/500 reads (12%) | called by muse, mutect2, varscan2
- SEC14L3 | c.*140C>T | 3'UTR (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- SEMA7A | c.1639+110C>T | Intron (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- SLC25A44 | c.*861G>T | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- SLC30A8 | c.*801T>C | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- SLC7A1 | c.*3064G>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- SORCS2 | c.*2377C>A | 3'UTR (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- SRRD | c.765-31T>C | Intron (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.-87G>T | 5'UTR (SNP) | VAF 7/158 reads (4%) | catalogued as COSV100602680; called by muse, mutect2
- STK32B | c.*290G>A | 3'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- SYT12 | c.*1779G>A | 3'UTR (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2, varscan2
- TLCD4 | c.*845A>G | 3'UTR (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- TM6SF1 | c.-13C>G | 5'UTR (SNP) | VAF 8/151 reads (5%) | catalogued as COSV99362550; called by muse, mutect2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 161/161 reads (100%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TRIM68 | c.*202A>G | 3'UTR (SNP) | VAF 53/122 reads (43%) | catalogued as rs561443068; called by muse, mutect2, varscan2
- UBP1 | chr3:33388545 T>C | 3'Flank (SNP) | VAF 9/78 reads (12%) | catalogued as rs1418059939; called by muse, mutect2, varscan2
- VAV3 | c.*854C>G | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2
- VMA21 | c.-13G>C | 5'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, varscan2
- WDR37 | c.726+161A>C | Intron (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- WNT7A | c.*1812C>A | 3'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- WWTR1 | c.-3-124A>T | Intron (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+825G>A | Intron (SNP) | VAF 44/80 reads (55%) | called by mutect2, varscan2
- ZMIZ1 | c.*1213A>T | 3'UTR (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- ZNF141 | c.*257A>T | 3'UTR (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2
- ZNF331 | c.*370C>T | 3'UTR (SNP) | VAF 44/44 reads (100%) | catalogued as rs897352406; called by muse, mutect2, varscan2
- ZNF815P | n.810G>C | RNA (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
